Somatic mutation profile of tumor specimen TCGA-17-Z062-01A (aliquot TCGA-17-Z062-01A-01W-0747-08) from TCGA case TCGA-17-Z062, project TCGA-LUAD (Lung Adenocarcinoma).
Specimen TCGA-17-Z062-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ada875f7-1ad8-4aac-9199-254484a934b4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-17-Z062-11A (Solid Tissue Normal), aliquot TCGA-17-Z062-11A-01W-0747-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/249f9c24-28fb-466e-ac78-7e66d16029d4

The open-access MAF lists 449 somatic variants for this specimen: 348 protein-altering or splice-affecting, 93 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 301, Silent 93, Nonsense Mutation 24, Splice Site 13, Splice Region 4, Frame Shift Del 4, Intron 3, RNA 2, 3'UTR 1, 5'Flank 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 11/47 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs11552822, CM085316, CM990358, COSV58683210, COSV58683289, COSV58686242, COSV58694349; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.310C>T p.Q104* | Nonsense Mutation (SNP) | VAF 33/194 reads (17%) | hotspot (GDC flag); catalogued as rs1567555934, COSV52694629; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6445C>A p.Q2149K (on ENST00000272895 / NM_173076.3; = p.Q1831K on NM_015657.3) | Missense Mutation (SNP) | VAF 9/241 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as CD080779; called by muse, mutect2
- ABCA9 | c.2590C>A p.L864M | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.493); catalogued as rs1182479732, COSV60632997; called by muse, mutect2
- ADGRL4 | c.1723A>G p.I575V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.549); catalogued as rs757073131; called by muse, mutect2, varscan2
- AKR1D1 | c.398C>A p.P133H | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM044567; called by muse, mutect2, varscan2
- ANK2 | c.7024G>T p.G2342* | Nonsense Mutation (SNP) | VAF 14/140 reads (10%) | catalogued as COSV100004859; called by muse, mutect2, varscan2
- ANO2 | c.37C>T p.R13C (on ENST00000356134 / NM_001278597.3; = p.R17C on NM_001278596.3) | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.978); catalogued as rs766546668, COSV59041835; called by muse, mutect2, varscan2
- ANXA10 | c.94G>T p.G32* | Nonsense Mutation (SNP) | VAF 14/151 reads (9%) | catalogued as COSV63737933, COSV63738897; called by muse, mutect2
- APBB2 | c.2171C>T p.P724L (on ENST00000295974 / NM_001166050.2; = p.P725L on NM_004307.2) | Missense Mutation (SNP) | VAF 72/378 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs748973343; called by muse, varscan2
- APOB | c.2917C>A p.L973M | Missense Mutation (SNP) | VAF 40/245 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.073); catalogued as rs886055592, COSV51955068; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ASTN2 | c.1265G>T p.R422L (on ENST00000313400 / NM_001365069.1; = p.R371L on NM_014010.5) | Missense Mutation (SNP) | VAF 22/213 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as rs550794735; called by muse, mutect2
- ATP10D | c.416G>A p.G139D | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV56706758; called by muse, varscan2
- AXDND1 | c.1005-1G>T p.X335_splice | Splice Site (SNP) | VAF 32/338 reads (9%) | catalogued as rs767956177; called by muse, mutect2
- BAZ1B | c.2827G>T p.D943Y | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as rs993270030; called by muse, mutect2, varscan2
- BRINP3 | c.299C>A p.P100H | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.756); catalogued as COSV66534613, COSV99054926; called by muse, mutect2, varscan2
- BRINP3 | c.298C>A p.P100T | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.198); catalogued as COSV66519989; called by muse, mutect2, varscan2
- CASQ1 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 8/174 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1207649338; called by muse, mutect2
- CCDC70 | c.405C>A p.D135E | Missense Mutation (SNP) | VAF 42/461 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.203); catalogued as rs772854835; called by muse, mutect2
- CD38 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 22/348 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56890720; called by muse, mutect2
- CDK15 | c.448+1G>T p.X150_splice (on ENST00000652192 / NM_001366386.2; = p.X99_splice on NM_139158.2) | Splice Site (SNP) | VAF 23/147 reads (16%) | catalogued as rs753183735; called by muse, mutect2, varscan2
- CEP70 | c.419A>G p.Q140R | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV99388805; called by muse, mutect2
- CLCA2 | c.1336G>T p.G446C | Missense Mutation (SNP) | VAF 44/351 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755747239; called by muse, mutect2, varscan2
- COL14A1 | c.4248G>C p.Q1416H | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV52857070; called by muse, mutect2
- CSGALNACT1 | c.1195C>A p.H399N | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as rs1462946421, COSV59974496; called by muse, mutect2, varscan2
- DAZL | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 19/175 reads (11%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.926); catalogued as rs939185441; called by muse, mutect2, varscan2
- DNAH1 | c.673C>A p.H225N | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV101325734; called by muse, mutect2, varscan2
- DNAI1 | c.1621A>G p.M541V | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1413318185; called by muse, mutect2, varscan2
- DNAI3 | c.1263+1G>C p.X421_splice | Splice Site (SNP) | VAF 20/238 reads (8%) | catalogued as COSV99642320; called by muse, mutect2
- FAM217A | c.1430_1431del p.I477Sfs*4 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | catalogued as rs1241533710; called by pindel, varscan2
- FAM47A | c.833C>A p.A278D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.82); catalogued as COSV60500661; called by muse, mutect2, varscan2
- FAM53C | c.921G>T p.Q307H | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV53511489; called by muse, mutect2, varscan2
- FCRL2 | c.915G>T p.R305S | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.141); catalogued as rs1311907928; called by muse, mutect2
- FLAD1 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as rs1054257; called by mutect2, varscan2
- FLG2 | c.4016C>T p.T1339I | Missense Mutation (SNP) | VAF 24/364 reads (7%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs895050171, COSV66174313; called by muse, mutect2
- FOXC2 | c.1477C>A p.P493T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.452); catalogued as COSV57445549; called by muse, mutect2
- GMEB2 | c.55C>G p.P19A | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1449097987; called by muse, mutect2, varscan2
- HCN1 | c.2243C>T p.P748L | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV57509115; called by muse, mutect2
- HERC4 | c.2266G>A p.E756K (on ENST00000395198 / NM_022079.3; = p.E748K on NM_015601.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/173 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53272008; called by muse, mutect2, varscan2
- IGKV1-27 | c.135C>A p.C45* | Nonsense Mutation (SNP) | VAF 7/180 reads (4%) | catalogued as rs1292131674; called by muse, mutect2
- IQGAP2 | c.2447G>A p.R816K | Missense Mutation (SNP) | VAF 24/171 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.348); catalogued as COSV57175537; called by muse, mutect2, varscan2
- ITGB8 | c.1876C>A p.H626N | Missense Mutation (SNP) | VAF 54/239 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.062); catalogued as COSV99751550; called by muse, mutect2, varscan2
- KCNH8 | c.457A>T p.R153* | Nonsense Mutation (SNP) | VAF 18/112 reads (16%) | catalogued as COSV60463964; called by muse, mutect2, varscan2
- KRTAP4-12 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 39/212 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs765414181; called by muse, mutect2, varscan2
- LGR5 | c.1896G>T p.E632D | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770141918; called by muse, mutect2, varscan2
- LHFPL1 | c.206G>C p.R69P | Missense Mutation (SNP) | VAF 27/169 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV64333341; called by muse, mutect2, varscan2
- LRIT3 | c.967G>T p.A323S | Missense Mutation (SNP) | VAF 32/286 reads (11%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.902); catalogued as COSV59988092; called by mutect2, varscan2
- LRP1B | c.12271G>T p.E4091* | Nonsense Mutation (SNP) | VAF 20/196 reads (10%) | catalogued as COSV67233190; called by muse, mutect2, varscan2
- LRRC7 | c.778T>A p.L260I (on ENST00000651989 / NM_001370785.2; = p.L227I on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT tolerated (0.83); PolyPhen benign (0.056); catalogued as COSV50659837; called by muse, mutect2
- MEDAG | c.539del p.P180Qfs*11 | Frame Shift Del (DEL) | VAF 24/237 reads (10%) | catalogued as rs1368498416, COSV66850199; called by mutect2, pindel, varscan2
- MRTFB | c.2404-1G>A p.X802_splice (on ENST00000571589 / NM_001365412.2; = p.X752_splice on NM_014048.4 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 31/265 reads (12%) | catalogued as rs1443245228; called by muse, mutect2, varscan2
- MSH3 | c.1654-1G>T p.X552_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | catalogued as COSV54166838, COSV99434545; called by muse, mutect2
- MUC16 | c.845C>A p.A282E | Missense Mutation (SNP) | VAF 48/528 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.382); catalogued as COSV67481298; called by muse, mutect2
- MYF6 | c.23C>G p.T8S | Missense Mutation (SNP) | VAF 13/133 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV57354089; called by muse, mutect2
- MYL10 | c.324C>A p.D108E | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as rs1260694575; called by muse, mutect2
- NAV2 | c.2243G>A p.R748Q (on ENST00000396087 / NM_001244963.2; = p.R725Q on NM_145117.5) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769722553; called by mutect2, varscan2
- NAV3 | c.1370G>T p.S457I | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs779639003; called by muse, mutect2, varscan2
- NAV3 | c.3959C>T p.T1320I | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.265); catalogued as rs748020281; called by muse, mutect2, varscan2
- NECTIN1 | c.1279_1281del p.K427del | In Frame Del (DEL) | VAF 11/93 reads (12%) | catalogued as rs1022251180; called by pindel, varscan2
- NEK1 | c.3152G>T p.C1051F | Missense Mutation (SNP) | VAF 10/99 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101455616; called by muse, mutect2
- NELL2 | c.521G>A p.R174K | Missense Mutation (SNP) | VAF 34/186 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61581697; called by muse, mutect2, varscan2
- NOTCH2 | c.4006-1G>T p.X1336_splice | Splice Site (SNP) | VAF 6/54 reads (11%) | catalogued as COSV99867092; called by muse, mutect2, varscan2
- NOTCH2 | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 28/226 reads (12%) | catalogued as COSV56696710; called by muse, mutect2, varscan2
- OR14C36 | c.157C>T p.L53F | Missense Mutation (SNP) | VAF 30/374 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV58602009; called by muse, mutect2
- OR4M1 | c.927G>T p.L309F | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV60061394, COSV60063199; called by muse, mutect2, varscan2
- OR4Q3 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 42/453 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as COSV59177477; called by muse, mutect2
- OR4S2 | c.327G>C p.E109D | Missense Mutation (SNP) | VAF 30/678 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as COSV56746448; called by muse, mutect2
- OR5D13 | c.546C>A p.D182E | Missense Mutation (SNP) | VAF 29/315 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100687063; called by muse, mutect2
- OR5I1 | c.58C>A p.P20T | Missense Mutation (SNP) | VAF 25/181 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.255); catalogued as COSV56887093; called by muse, mutect2, varscan2
- OR5L2 | c.359A>G p.Y120C | Missense Mutation (SNP) | VAF 77/501 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs534871810; called by muse, mutect2, varscan2
- OR5P3 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1391660594; called by muse, mutect2, varscan2
- P2RX7 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 20/296 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.72); catalogued as rs757160496; called by muse, mutect2
- PCDH15 | c.1619C>A p.S540* | Nonsense Mutation (SNP) | VAF 61/343 reads (18%) | catalogued as COSV100221904; called by muse, mutect2, varscan2
- PHLDB2 | c.3506G>A p.R1169Q (on ENST00000393925 / NM_001134439.2; = p.R1126Q on NM_145753.2) | Missense Mutation (SNP) | VAF 37/325 reads (11%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.777); catalogued as rs140319291; called by muse, mutect2, varscan2
- PLA2R1 | c.3437A>G p.K1146R | Missense Mutation (SNP) | VAF 29/347 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs980127959; called by muse, mutect2
- PLPPR4 | c.1421C>T p.P474L | Missense Mutation (SNP) | VAF 24/277 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.115); catalogued as COSV100926714, COSV64566332; called by muse, mutect2
- POU6F2 | c.1181C>A p.P394H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757853402; called by muse, mutect2, varscan2
- PRAMEF1 | c.293G>A p.W98* | Nonsense Mutation (SNP) | VAF 34/341 reads (10%) | catalogued as rs763270899, COSV60009056; called by muse, mutect2
- PRICKLE1 | c.2156G>T p.R719L | Missense Mutation (SNP) | VAF 46/220 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.019); catalogued as COSV100454417; called by muse, mutect2, varscan2
- PSG3 | c.84G>T p.W28C | Missense Mutation (SNP) | VAF 70/592 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100548901; called by muse, mutect2, varscan2
- PSKH2 | c.1047G>T p.Q349H | Missense Mutation (SNP) | VAF 16/311 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1169994593; called by muse, mutect2
- PTPN13 | c.7093G>A p.V2365M (on ENST00000411767 / NM_080683.3; = p.V2346M on NM_006264.3) | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.048); catalogued as rs756554168; called by muse, mutect2, varscan2
- PTPRB | c.3791C>A p.P1264H | Missense Mutation (SNP) | VAF 15/172 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54250940; called by muse, mutect2
- RAP2B | c.152C>T p.S51L | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV60257412; called by muse, mutect2
- RCOR2 | c.571C>T p.R191W | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs201796742; called by muse, mutect2, varscan2
- RP1L1 | c.4087G>A p.G1363R | Missense Mutation (SNP) | VAF 30/230 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.075); catalogued as COSV66751341; called by muse, varscan2
- RPTN | c.1952C>A p.P651H | Missense Mutation (SNP) | VAF 34/354 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); catalogued as COSV60169801; called by muse, mutect2
- RYR2 | c.4289T>C p.V1430A | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.814); catalogued as COSV63709853; called by muse, mutect2, varscan2
- SAMD7 | c.449T>A p.L150Q | Missense Mutation (SNP) | VAF 12/172 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.087); catalogued as COSV100156963, COSV99045847; called by muse, mutect2
- SATB1 | c.1978C>A p.Q660K | Missense Mutation (SNP) | VAF 34/247 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58667979; called by muse, mutect2, varscan2
- SCFD2 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV66368590; called by muse, mutect2
- SERPINA1 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM900179; called by muse, mutect2, varscan2
- SIGLEC1 | c.2797G>T p.D933Y | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52462202, COSV99163175; called by muse, mutect2
- SLC12A9 | c.89G>T p.G30V | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV51931645; called by muse, mutect2, varscan2
- SLC17A6 | c.747C>T p.Y249= | Splice Region (SNP) | VAF 21/152 reads (14%) | catalogued as rs753049319, COSV54133640; called by muse, mutect2, varscan2
- SLC24A3 | c.1180G>T p.G394C | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.662); catalogued as COSV100043733; called by muse, mutect2, varscan2
- SLC26A7 | c.432G>T p.R144S | Missense Mutation (SNP) | VAF 16/143 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52595066; called by muse, mutect2, varscan2
- SLC38A4 | c.824C>G p.P275R | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.029); catalogued as COSV99872913; called by muse, mutect2
- SPAM1 | c.198G>T p.E66D | Missense Mutation (SNP) | VAF 19/128 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as rs1401409367, COSV56143447; called by muse, mutect2, varscan2
- SRGAP1 | c.1540G>T p.D514Y | Missense Mutation (SNP) | VAF 89/546 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as COSV61894428; called by muse, mutect2, varscan2
- SSRP1 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV53478583; called by muse, mutect2
- STAP1 | c.551G>T p.R184L | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55330958; called by muse, mutect2, varscan2
- SUCO | c.1783C>T p.L595F | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1224916510; called by muse, mutect2, varscan2
- SYT2 | c.922C>T p.P308S | Missense Mutation (SNP) | VAF 71/395 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66142532; called by muse, mutect2, varscan2
- TAF1A | c.1111G>T p.E371* | Nonsense Mutation (SNP) | VAF 27/167 reads (16%) | catalogued as COSV61918751; called by muse, mutect2, varscan2
- TEX44 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 18/100 reads (18%) | SIFT tolerated (0.33); PolyPhen benign (0.111); catalogued as rs990283936; called by muse, mutect2, varscan2
- TG | c.5086G>A p.G1696S | Missense Mutation (SNP) | VAF 45/575 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV55090713; called by muse, mutect2
- TGM7 | c.1203C>A p.N401K | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV71772553; called by muse, mutect2, varscan2
- TNR | c.1091T>C p.L364P | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV99687369; called by muse, mutect2
- TRPC5 | c.366C>A p.S122R | Missense Mutation (SNP) | VAF 100/302 reads (33%) | SIFT tolerated (0.51); PolyPhen benign (0.009); catalogued as rs143012451, COSV53298726; called by muse, mutect2, varscan2
- TRPV5 | c.1434C>A p.F478L | Missense Mutation (SNP) | VAF 27/146 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.945); catalogued as COSV54683901; called by muse, varscan2
- TTC17 | c.1238G>T p.R413L | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV50015829; called by muse, mutect2, varscan2
- TTF2 | c.1475C>T p.P492L | Missense Mutation (SNP) | VAF 11/111 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.367); catalogued as COSV65632291; called by muse, mutect2
- UBXN7 | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 26/232 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.247); catalogued as COSV56353480; called by muse, mutect2, varscan2
- UGT2A2 | c.586C>A p.P196T | Missense Mutation (SNP) | VAF 10/86 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV99683894; called by muse, varscan2
- USH2A | c.6488G>T p.W2163L | Missense Mutation (SNP) | VAF 30/300 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as CM159128, COSV56341128; called by muse, mutect2
- USH2A | c.3983G>T p.G1328V | Missense Mutation (SNP) | VAF 17/283 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV56328740; called by muse, mutect2
- USH2A | c.3982G>T p.G1328C | Missense Mutation (SNP) | VAF 16/284 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV56398618; called by muse, mutect2
- USP29 | c.1645C>G p.L549V | Missense Mutation (SNP) | VAF 14/294 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.372); catalogued as COSV54139866; called by muse, mutect2
- WDR17 | c.1891G>T p.D631Y | Missense Mutation (SNP) | VAF 24/257 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1561179464; called by muse, mutect2
- WNT7A | c.171C>A p.D57E | Missense Mutation (SNP) | VAF 15/103 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs766374751, COSV53202118; called by muse, mutect2, varscan2
- XRCC4 | c.962T>C p.L321S (on ENST00000338635 / NM_022406.4; = p.L319S on NM_003401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 47/433 reads (11%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.713); catalogued as rs1248685967; called by muse, mutect2, varscan2
- ZFC3H1 | c.5787G>T p.Q1929H | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.979); catalogued as COSV101110687; called by muse, mutect2
- ZNF133 | c.1147G>T p.A383S (on ENST00000316358 / NM_001352454.2; = p.A382S on NM_003434.7 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as CM142682, COSV60367005; called by muse, mutect2, varscan2
- ZNF335 | c.2429dup p.T811Hfs*27 | Frame Shift Ins (INS) | VAF 4/28 reads (14%) | catalogued as rs1452778677; called by pindel, varscan2
- ZNF648 | c.852C>A p.C284* | Nonsense Mutation (SNP) | VAF 4/20 reads (20%) | catalogued as rs922766588; called by muse, mutect2
- AC104389.6 | c.395T>C p.L132P | Missense Mutation (SNP) | VAF 16/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- ADAMTS16 | c.735G>T p.K245N | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); called by muse, mutect2, varscan2
- ADAMTS19 | c.1218T>A p.F406L | Missense Mutation (SNP) | VAF 35/191 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- ADAMTS20 | c.5409C>G p.S1803R | Missense Mutation (SNP) | VAF 26/200 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.149); called by muse, mutect2, varscan2
- ADAMTSL1 | c.590C>G p.S197C | Missense Mutation (SNP) | VAF 14/103 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.299); called by muse, mutect2, varscan2
- ADGRL3 | c.364G>T p.E122* (on ENST00000506720 / NM_001322402.2; = p.E54* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 5/47 reads (11%) | called by muse, varscan2
- ADGRL3 | c.572G>A p.C191Y (on ENST00000506720 / NM_001322402.2; = p.C123Y on NM_015236.6) | Missense Mutation (SNP) | VAF 39/425 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- ADGRL3 | c.2086G>T p.E696* (on ENST00000506720 / NM_001322402.2; = p.E628* on NM_015236.6) | Nonsense Mutation (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- ANK3 | c.2633G>T p.G878V (on ENST00000280772 / NM_001320874.2; = p.G12V on NM_001149.3) | Missense Mutation (SNP) | VAF 22/408 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- ANO5 | c.612G>T p.Q204H | Missense Mutation (SNP) | VAF 14/331 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.212); called by muse, mutect2
- AOAH | c.847-2A>T p.X283_splice | Splice Site (SNP) | VAF 14/134 reads (10%) | called by mutect2, varscan2
- APOB | c.5536G>T p.A1846S | Missense Mutation (SNP) | VAF 60/412 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- ARHGEF25 | c.921G>T p.K307N | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ASPM | c.1393A>G p.I465V | Missense Mutation (SNP) | VAF 39/187 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ASTN2 | c.631-1G>T p.X211_splice | Splice Site (SNP) | VAF 14/108 reads (13%) | called by muse, varscan2
- ATG7 | c.220G>T p.A74S | Missense Mutation (SNP) | VAF 46/370 reads (12%) | SIFT tolerated (0.49); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ATG9B | c.736C>G p.P246A | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.007); called by muse, mutect2
- ATM | c.6715A>G p.M2239V | Missense Mutation (SNP) | VAF 16/354 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2
- AXDND1 | c.1005G>T p.R335S | Missense Mutation (SNP) | VAF 32/344 reads (9%) | SIFT tolerated (0.34); PolyPhen benign (0.286); called by muse, mutect2
- BACH1 | c.1053G>T p.L351F | Missense Mutation (SNP) | VAF 30/359 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.388); called by muse, mutect2
- BBS9 | c.2633-1G>T p.X878_splice (on ENST00000242067 / NM_001348036.1; = p.X838_splice on NM_014451.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 73/378 reads (19%) | called by muse, mutect2, varscan2
- C17orf98 | c.56G>T p.G19V | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- C7orf25 | c.799T>A p.C267S | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0.408); called by muse, mutect2
- C7orf26 | c.276G>C p.Q92H | Missense Mutation (SNP) | VAF 25/198 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CASD1 | c.928A>G p.T310A | Missense Mutation (SNP) | VAF 29/329 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.253); called by muse, mutect2
- CBLB | c.2320G>T p.D774Y | Missense Mutation (SNP) | VAF 18/253 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.085); called by muse, mutect2
- CCDC38 | c.743C>A p.A248E | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CCDC73 | c.279+1G>T p.X93_splice | Splice Site (SNP) | VAF 39/292 reads (13%) | called by muse, mutect2, varscan2
- CCDC83 | c.414G>T p.E138D | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.996); called by muse, mutect2
- CCR3 | c.572C>G p.T191R | Missense Mutation (SNP) | VAF 31/328 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.222); called by muse, mutect2
- CD53 | c.371G>C p.R124P | Missense Mutation (SNP) | VAF 18/192 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.518); called by muse, mutect2
- CDH18 | c.466G>C p.A156P | Missense Mutation (SNP) | VAF 26/147 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDH7 | c.860C>T p.A287V | Missense Mutation (SNP) | VAF 25/237 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CEP126 | c.1585C>T p.H529Y | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- CFAP44 | c.1173A>T p.I391= | Splice Region (SNP) | VAF 14/179 reads (8%) | called by muse, mutect2
- CFAP61 | c.1060T>A p.Y354N | Missense Mutation (SNP) | VAF 43/203 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CFAP61 | c.3029T>A p.M1010K | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- CFHR3 | c.904T>G p.C302G | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHRM2 | c.1218G>T p.M406I | Missense Mutation (SNP) | VAF 22/401 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); called by muse, mutect2
- CHRNA3 | c.942T>A p.F314L | Missense Mutation (SNP) | VAF 7/146 reads (5%) | SIFT tolerated (0.59); PolyPhen probably damaging (0.999); called by muse, mutect2
- CHST5 | c.1072G>T p.A358S | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.035); called by muse, mutect2
- CIC | c.1471G>T p.G491C | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.972); called by muse, mutect2
- CMTR2 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNKSR2 | c.2498A>T p.Q833L | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- COL11A1 | c.4765G>T p.D1589Y | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2
- COL22A1 | c.2641G>T p.E881* | Nonsense Mutation (SNP) | VAF 23/205 reads (11%) | called by muse, mutect2, varscan2
- CPB1 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CR1L | c.896A>T p.E299V | Missense Mutation (SNP) | VAF 31/420 reads (7%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.763); called by muse, mutect2
- CRISP2 | c.256G>C p.E86Q | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.1); called by muse, mutect2
- CSGALNACT1 | c.977C>A p.T326N | Missense Mutation (SNP) | VAF 43/362 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CTPS2 | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 31/177 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- CXCR2 | c.228C>G p.S76R | Missense Mutation (SNP) | VAF 7/210 reads (3%) | SIFT tolerated (0.18); PolyPhen benign (0.114); called by muse, mutect2
- DCDC1 | c.3317T>A p.L1106H (on ENST00000597505 / NM_001367979.1; = p.L213H on NM_020869.3) | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2
- DGKG | c.215G>A p.S72N | Missense Mutation (SNP) | VAF 16/216 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2
- DLEC1 | c.4277C>A p.A1426D | Missense Mutation (SNP) | VAF 37/332 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- DNMT3A | c.1076A>G p.Y359C | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- DSCAML1 | c.4136C>A p.P1379H (on ENST00000321322; = p.P1319H on NM_020693.4) | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DST | c.11894G>T p.R3965M (on ENST00000361203 / NM_001374722.1; = p.R1553M on NM_015548.5) | Missense Mutation (SNP) | VAF 63/612 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- DZIP1L | c.708G>T p.Q236H | Missense Mutation (SNP) | VAF 15/175 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); called by muse, mutect2
- DZIP3 | c.101T>A p.L34Q | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.694); called by muse, mutect2
- EIF2S3 | c.1408G>T p.D470Y | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- ENAM | c.3233G>A p.R1078K | Missense Mutation (SNP) | VAF 26/279 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.192); called by muse, mutect2
- ERCC6 | c.237G>C p.Q79H | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); called by muse, mutect2
- ERN2 | c.847C>A p.Q283K | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT tolerated (0.66); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- EXOC2 | c.1606G>A p.G536S | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT tolerated (0.96); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- FAT3 | c.7480C>A p.P2494T | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FMO2 | c.64G>T p.V22L | Missense Mutation (SNP) | VAF 44/502 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.028); called by muse, mutect2
- GAST | c.4C>A p.Q2K | Missense Mutation (SNP) | VAF 28/438 reads (6%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.059); called by muse, mutect2
- GHR | c.1445del p.S482* | Frame Shift Del (DEL) | VAF 17/107 reads (16%) | called by mutect2, pindel, varscan2
- GLI2 | c.4564C>T p.Q1522* (on ENST00000361492 / NM_001374353.1; = p.Q1539* on NM_005270.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 17/174 reads (10%) | called by muse, mutect2, varscan2
- GLYAT | c.796G>T p.D266Y | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- GNA13 | c.229G>C p.D77H | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- GPR107 | c.797A>T p.Y266F | Missense Mutation (SNP) | VAF 24/185 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- GPR31 | c.836C>A p.P279H | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GREB1 | c.570G>C p.K190N | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- GRID2 | c.2857A>T p.T953S | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- GRM8 | c.2701A>G p.I901V | Missense Mutation (SNP) | VAF 19/254 reads (7%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- GTPBP10 | c.928A>C p.M310L | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2
- HOXD10 | c.54G>T p.L18F | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- HYOU1 | c.303G>T p.Q101H | Missense Mutation (SNP) | VAF 12/253 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.317); called by muse, mutect2
- IMMT | c.1808G>A p.C603Y | Missense Mutation (SNP) | VAF 29/184 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- IMPG2 | c.3234-2A>T p.X1078_splice | Splice Site (SNP) | VAF 29/159 reads (18%) | called by muse, mutect2, varscan2
- ISM2 | c.814G>C p.D272H | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- ITGAV | c.2483A>T p.Q828L | Missense Mutation (SNP) | VAF 33/276 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- ITK | c.711T>A p.Y237* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- KCNB1 | c.1995C>A p.N665K | Missense Mutation (SNP) | VAF 29/119 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.271); called by muse, mutect2, varscan2
- KCNH7 | c.2456G>T p.G819V | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- KIAA1210 | c.3399G>T p.Q1133H | Missense Mutation (SNP) | VAF 57/159 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- KIF13B | c.3043G>T p.V1015F | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- KRTAP9-3 | c.461G>T p.C154F | Missense Mutation (SNP) | VAF 74/361 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, varscan2
- L3MBTL1 | c.1161G>T p.E387D (on ENST00000418998 / NM_001377303.1; = p.E297D on NM_015478.7) | Missense Mutation (SNP) | VAF 41/191 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- LARP1 | c.2408T>A p.V803E (on ENST00000518297 / NM_033551.3; = p.V726E on NM_015315.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- LARP4 | c.1705T>C p.S569P | Missense Mutation (SNP) | VAF 18/150 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.051); called by muse, varscan2
- LCE3A | c.100C>A p.P34T | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- LPA | c.4298C>G p.T1433S | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT tolerated (0.49); PolyPhen benign (0); called by muse, mutect2
- LRP12 | c.533G>T p.C178F | Missense Mutation (SNP) | VAF 27/175 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- M1AP | c.152T>C p.L51P | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- MAGED2 | c.1414G>T p.A472S | Missense Mutation (SNP) | VAF 11/92 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- MAP4K3 | c.1442C>T p.P481L | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MARCHF10 | c.383-1G>C p.X128_splice | Splice Site (SNP) | VAF 16/101 reads (16%) | called by muse, mutect2, varscan2
- MBNL1 | c.332C>T p.P111L | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- MCM5 | c.1504G>T p.D502Y | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- MED12L | c.4169A>G p.D1390G | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- MFF | c.670G>T p.A224S | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); called by muse, mutect2
- MLH3 | c.3825A>T p.L1275F (on ENST00000355774 / NM_001040108.2; = p.L1251F on NM_014381.3) | Missense Mutation (SNP) | VAF 15/100 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2
- MME | c.508G>T p.A170S | Missense Mutation (SNP) | VAF 26/253 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- MOV10 | c.563G>C p.C188S | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MS4A12 | c.455A>T p.E152V | Missense Mutation (SNP) | VAF 81/586 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MS4A3 | c.49C>A p.H17N | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYH13 | c.4570G>T p.G1524C | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- MYH8 | c.5176C>A p.L1726I | Missense Mutation (SNP) | VAF 32/393 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.838); called by muse, mutect2
- NALCN | c.2290C>A p.R764S | Missense Mutation (SNP) | VAF 46/402 reads (11%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.544); called by mutect2, varscan2
- NCKAP5L | c.1169G>T p.R390M | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- NDST3 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT tolerated (0.44); PolyPhen benign (0.026); called by muse, mutect2
- NDUFB5 | c.343-2A>T p.X115_splice | Splice Site (SNP) | VAF 14/78 reads (18%) | called by mutect2, varscan2
- NEO1 | c.3122G>T p.G1041V | Missense Mutation (SNP) | VAF 5/102 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NRIP1 | c.2656G>T p.A886S | Missense Mutation (SNP) | VAF 34/448 reads (8%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2
- NTRK1 | c.1621G>A p.V541M | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR10G8 | c.440C>A p.T147N | Missense Mutation (SNP) | VAF 48/407 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR10Q1 | c.547C>T p.L183F | Missense Mutation (SNP) | VAF 10/101 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.127); called by muse, mutect2
- OR1C1 | c.716C>A p.S239Y | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR4C11 | c.348G>T p.M116I | Missense Mutation (SNP) | VAF 10/202 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.429); called by muse, mutect2
- OR4D9 | c.431T>A p.L144H | Missense Mutation (SNP) | VAF 22/164 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR4N5 | c.49C>A p.L17M | Missense Mutation (SNP) | VAF 156/720 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR5D14 | c.666C>G p.F222L | Missense Mutation (SNP) | VAF 15/206 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.097); called by muse, mutect2
- OR5P3 | c.758G>T p.G253V | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR6C68 | c.415T>A p.C139S | Missense Mutation (SNP) | VAF 29/264 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- OR7G2 | c.104T>A p.L35H | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- OS9 | c.1894G>T p.E632* | Nonsense Mutation (SNP) | VAF 14/91 reads (15%) | called by muse, mutect2, varscan2
- OTOL1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- OTOL1 | c.1279G>T p.A427S | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- PAK5 | c.2029C>A p.L677I | Missense Mutation (SNP) | VAF 97/441 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.749); called by muse, mutect2, varscan2
- PCDH11X | c.1957C>A p.R653S | Missense Mutation (SNP) | VAF 36/136 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PCDH11Y | c.2464A>T p.I822F (on ENST00000400457 / NM_032973.2; = p.I811F on NM_032971.3) | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.167); called by muse, mutect2, varscan2
- PCDH11Y | c.3442C>A p.P1148T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- PCDH15 | c.4876G>T p.A1626S (on ENST00000644397 / NM_001354429.2; = p.A1568S on NM_001142771.2) | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT tolerated, low confidence (0.91); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PCDH7 | c.2519G>A p.W840* | Nonsense Mutation (SNP) | VAF 25/308 reads (8%) | called by muse, mutect2
- PCDHB15 | c.1673C>A p.S558* | Nonsense Mutation (SNP) | VAF 7/47 reads (15%) | called by muse, mutect2, varscan2
- PCDHGA1 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PDZD8 | c.1429G>T p.G477C | Missense Mutation (SNP) | VAF 86/411 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- PGA3 | c.199C>A p.P67T | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- PLEKHG4B | c.1414G>C p.D472H (on ENST00000283426; = p.D828H on NM_052909.5) | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- PLG | c.311A>T p.K104M | Missense Mutation (SNP) | VAF 12/120 reads (10%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.849); called by muse, mutect2
- PLG | c.1720C>A p.P574T | Missense Mutation (SNP) | VAF 10/122 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); called by muse, mutect2
- PNLIP | c.748G>T p.E250* | Nonsense Mutation (SNP) | VAF 60/267 reads (22%) | called by muse, mutect2, varscan2
- POTEA | c.239G>T p.R80I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by mutect2, varscan2
- PRAME | c.598A>T p.K200* | Nonsense Mutation (SNP) | VAF 14/125 reads (11%) | called by muse, mutect2, varscan2
- PRKN | c.1069G>T p.G357C | Missense Mutation (SNP) | VAF 18/311 reads (6%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.859); called by muse, mutect2
- PROS1 | c.1292C>T p.P431L | Missense Mutation (SNP) | VAF 50/364 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2, varscan2
- PSAP | c.302A>C p.N101T | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- PSG7 | c.32A>T p.Q11L | Missense Mutation (SNP) | VAF 11/286 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- PSPC1 | c.590G>A p.G197E | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- PTH2R | c.1487T>A p.V496D | Missense Mutation (SNP) | VAF 14/157 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PTPRN | c.510C>A p.S170R | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.062); called by muse, mutect2
- PYDC2 | c.139G>T p.V47L | Missense Mutation (SNP) | VAF 15/183 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.113); called by muse, mutect2
- RAMP3 | c.62G>A p.G21E | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAPGEFL1 | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 15/98 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.457); called by muse, mutect2, varscan2
- RASGEF1C | c.613G>T p.A205S | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- RASGRF2 | c.2388G>T p.E796D | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM42 | c.362G>T p.G121V | Missense Mutation (SNP) | VAF 15/249 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.963); called by muse, mutect2
- RELN | c.920G>A p.S307N | Missense Mutation (SNP) | VAF 80/618 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- RIN1 | c.2042A>T p.Y681F | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- RIPK1 | c.1728T>C p.F576= | Splice Region (SNP) | VAF 10/91 reads (11%) | called by muse, mutect2, varscan2
- RPS6KA6 | c.716A>T p.Y239F | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- RSAD2 | c.289T>G p.S97A | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- RTTN | c.3845A>T p.H1282L | Missense Mutation (SNP) | VAF 17/186 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.52); called by muse, mutect2, varscan2
- RUNX1T1 | c.346C>T p.P116S (on ENST00000265814 / NM_001198628.1; = p.P89S on NM_004349.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/217 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- RYR3 | c.1011C>A p.D337E | Missense Mutation (SNP) | VAF 7/121 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.025); called by muse, mutect2
- SALL1 | c.935G>T p.G312V | Missense Mutation (SNP) | VAF 23/243 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.708); called by muse, mutect2
- SAMD9 | c.141G>T p.K47N | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.075); called by muse, mutect2
- SBF1 | c.3688G>T p.G1230C | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SCN8A | c.5669T>A p.L1890Q | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SEMA6A | c.2181G>T p.M727I | Missense Mutation (SNP) | VAF 54/442 reads (12%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SEPTIN6 | c.798G>T p.E266D | Missense Mutation (SNP) | VAF 47/169 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SETBP1 | c.1580C>A p.A527D | Missense Mutation (SNP) | VAF 33/306 reads (11%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- SETX | c.7498G>T p.A2500S | Missense Mutation (SNP) | VAF 17/223 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.007); called by muse, mutect2
- SEZ6L | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 21/337 reads (6%) | called by muse, mutect2
- SFMBT2 | c.271T>A p.Y91N | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHOC1 | c.3629T>C p.I1210T | Missense Mutation (SNP) | VAF 17/135 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC17A6 | c.1590C>A p.D530E | Missense Mutation (SNP) | VAF 14/135 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLC5A3 | c.1225A>T p.I409F | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.36); called by muse, mutect2
- SON | c.2635G>T p.G879C | Missense Mutation (SNP) | VAF 11/96 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, varscan2
- SPEN | c.7870C>G p.R2624G | Missense Mutation (SNP) | VAF 40/387 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SPTAN1 | c.2360del p.Q787Rfs*30 | Frame Shift Del (DEL) | VAF 8/57 reads (14%) | called by mutect2, pindel, varscan2
- SPTBN1 | c.1250A>C p.Q417P | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- STIL | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 24/260 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2
- STK19 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- STON2 | c.1331A>C p.Q444P (on ENST00000649389 / NM_001366849.2; = p.Q387P on NM_001256430.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.522); called by muse, mutect2
- SVEP1 | c.3194G>T p.G1065V | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SZT2 | c.4454C>T p.S1485L (on ENST00000634258 / NM_001365999.1; = p.S1428L on NM_015284.4) | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2
- TCAF1 | c.98G>C p.G33A | Missense Mutation (SNP) | VAF 13/166 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2
- TEAD4 | c.718G>T p.D240Y | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- THSD7A | c.2752T>C p.C918R | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD7A | c.1164G>T p.R388S | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMTC4 | c.170A>C p.Q57P (on ENST00000376234 / NM_001350577.2; = p.Q76P on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.044); called by mutect2, varscan2
- TPR | c.6719C>G p.S2240C | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRAF6 | c.1466A>T p.K489M | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRAPPC11 | c.2287C>A p.P763T | Missense Mutation (SNP) | VAF 25/314 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAV23DV6 | c.53G>T p.W18L | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.2); PolyPhen benign (0.031); called by muse, mutect2
- TRIM29 | c.770C>T p.T257I | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TRPS1 | c.350C>G p.A117G (on ENST00000220888 / NM_001330599.2; = p.A130G on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.081); called by muse, mutect2
- TSBP1 | c.1640A>T p.Q547L (on ENST00000617061; = p.T553= on NM_006781.5) | Missense Mutation (SNP) | VAF 38/378 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- UBR4 | c.5423C>T p.A1808V | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (1); PolyPhen probably damaging (0.956); called by muse, mutect2
- UNC45B | c.125T>A p.L42Q | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- USP29 | c.1393C>A p.L465I | Missense Mutation (SNP) | VAF 7/196 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.437); called by muse, mutect2
- UTS2 | c.202C>A p.L68I | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- VAT1L | c.814T>A p.Y272N | Missense Mutation (SNP) | VAF 57/418 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WASF1 | c.1034C>A p.T345N | Missense Mutation (SNP) | VAF 18/328 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.055); called by muse, mutect2
- WDR49 | c.710T>A p.V237E (on ENST00000308378 / NM_001366158.1; = p.V578E on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/422 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2
- WNK4 | c.1625C>G p.A542G | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- XKR3 | c.1017G>T p.Q339H | Missense Mutation (SNP) | VAF 57/338 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZAN | c.7462C>T p.Q2488* | Nonsense Mutation (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- ZBTB49 | c.605G>T p.C202F | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.339); called by muse, mutect2
- ZBTB9 | c.611G>T p.G204V | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- ZFAT | c.2449G>T p.A817S | Missense Mutation (SNP) | VAF 16/226 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.715); called by muse, mutect2
- ZFHX4 | c.3265C>G p.P1089A | Missense Mutation (SNP) | VAF 48/437 reads (11%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF569 | c.66G>A p.W22* | Nonsense Mutation (SNP) | VAF 7/156 reads (4%) | called by muse, mutect2
- ZNF585A | c.742G>T p.G248C (on ENST00000292841 / NM_001288800.2; = p.G193C on NM_152655.3) | Missense Mutation (SNP) | VAF 45/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF608 | c.2842G>T p.D948Y | Missense Mutation (SNP) | VAF 16/113 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZNF69 | c.173G>T p.R58M (on ENST00000429654 / NM_001364730.1; = p.R44M on NM_021915.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/172 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- ZNF80 | c.371G>C p.R124P | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.051); called by muse, varscan2
- ZNF98 | c.156G>T p.V52= | Splice Region (SNP) | VAF 18/103 reads (17%) | called by muse, mutect2, varscan2
- AC104389.6 | c.396G>T p.L132= | Silent (SNP) | VAF 16/184 reads (9%) | called by muse, varscan2
- ANKMY1 | c.2049A>G p.L683= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs1203802116; called by muse, mutect2, varscan2
- ANO3 | c.108C>A p.S36= | Silent (SNP) | VAF 61/487 reads (13%) | catalogued as COSV56802864; called by muse, mutect2, varscan2
- ASTN2 | c.912G>T p.R304= | Silent (SNP) | VAF 20/136 reads (15%) | catalogued as COSV57777854; called by muse, mutect2, varscan2
- C17orf64 | c.585C>A p.P195= | Silent (SNP) | VAF 12/81 reads (15%) | called by muse, mutect2, varscan2
- C6orf118 | c.141G>T p.R47= | Silent (SNP) | VAF 20/148 reads (14%) | catalogued as COSV57817086; called by muse, mutect2, varscan2
- CACNG5 | c.270G>A p.T90= | Silent (SNP) | VAF 12/106 reads (11%) | catalogued as rs144101002; called by muse, mutect2
- CALCOCO1 | c.1155G>T p.L385= | Silent (SNP) | VAF 25/171 reads (15%) | called by muse, mutect2, varscan2
- CALCR | c.1008C>T p.V336= (on ENST00000649521 / NM_001164737.2; = p.V320= on NM_001742.4) | Silent (SNP) | VAF 14/170 reads (8%) | called by muse, mutect2
- CD163L1 | c.3834C>A p.A1278= | Silent (SNP) | VAF 65/333 reads (20%) | catalogued as COSV58013204; called by muse, mutect2, varscan2
- CDH12 | c.594C>A p.V198= | Silent (SNP) | VAF 15/123 reads (12%) | catalogued as COSV66431471; called by muse, mutect2, varscan2
- CENPB | c.123G>T p.T41= | Silent (SNP) | VAF 9/37 reads (24%) | called by muse, mutect2, varscan2
- CHD8 | c.6963G>T p.V2321= (on ENST00000646647 / NM_001170629.2; = p.V2042= on NM_020920.4) | Silent (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- CHST1 | c.315C>A p.T105= | Silent (SNP) | VAF 16/86 reads (19%) | catalogued as COSV57325594; called by muse, mutect2, varscan2
- COL19A1 | c.1398A>T p.L466= | Silent (SNP) | VAF 50/498 reads (10%) | catalogued as COSV59567815; called by muse, mutect2
- COL4A5 | c.4503A>G p.Q1501= | Silent (SNP) | VAF 26/166 reads (16%) | catalogued as COSV60367108; called by muse, mutect2, varscan2
- COL6A6 | c.3474G>T p.V1158= | Silent (SNP) | VAF 8/111 reads (7%) | called by muse, mutect2
- CTTNBP2 | c.2010C>T p.P670= | Silent (SNP) | VAF 14/276 reads (5%) | catalogued as rs1428964846, COSV99355168; called by muse, mutect2
- CYBB | c.1515G>T p.L505= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as CD106283, COSV66086183; called by muse, mutect2, varscan2
- DCLK3 | c.165G>A p.G55= | Silent (SNP) | VAF 29/170 reads (17%) | called by muse, mutect2, varscan2
- DDX20 | c.1983A>T p.S661= | Silent (SNP) | VAF 24/186 reads (13%) | called by muse, mutect2, varscan2
- DLGAP2 | c.990G>T p.A330= | Silent (SNP) | VAF 22/196 reads (11%) | catalogued as COSV101421075; called by muse, mutect2
- DOCK2 | c.901C>A p.R301= | Silent (SNP) | VAF 33/243 reads (14%) | catalogued as COSV56973347; called by muse, mutect2, varscan2
- DUT | c.312C>T p.A104= (on ENST00000331200 / NM_001025248.2; = p.A16= on NM_001948.4) | Silent (SNP) | VAF 6/45 reads (13%) | catalogued as COSV58664536; called by muse, mutect2
- EPHA3 | c.1017C>T p.T339= | Silent (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- F5 | c.2877C>A p.I959= | Silent (SNP) | VAF 49/517 reads (9%) | catalogued as COSV63125243; called by muse, mutect2
- FAM47B | c.729C>G p.R243= | Silent (SNP) | VAF 9/67 reads (13%) | catalogued as COSV100264383; called by muse, mutect2, varscan2
- FLG | c.5430G>A p.Q1810= | Silent (SNP) | VAF 67/470 reads (14%) | catalogued as rs1315567892; called by muse, mutect2, varscan2
- GABRR1 | c.402T>C p.S134= | Silent (SNP) | VAF 58/724 reads (8%) | called by muse, mutect2
- GIMAP8 | c.1359G>T p.A453= | Silent (SNP) | VAF 17/279 reads (6%) | called by muse, mutect2
- GMEB1 | c.912C>T p.L304= | Silent (SNP) | VAF 23/155 reads (15%) | catalogued as COSV53795880, COSV99603113; called by muse, mutect2, varscan2
- GRAP2 | c.741C>A p.G247= | Silent (SNP) | VAF 16/112 reads (14%) | called by muse, mutect2, varscan2
- HFM1 | c.2121T>C p.H707= | Silent (SNP) | VAF 22/254 reads (9%) | catalogued as rs1389582939, COSV54028382; called by muse, mutect2
- HGFAC | c.150A>T p.T50= | Silent (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- HOXB13 | c.816G>A p.K272= | Silent (SNP) | VAF 27/127 reads (21%) | called by muse, mutect2, varscan2
- IGSF3 | c.2073G>T p.L691= (on ENST00000369486 / NM_001007237.3; = p.L711= on NM_001542.4) | Silent (SNP) | VAF 28/394 reads (7%) | catalogued as rs1383337764; called by muse, mutect2
- IRX2 | c.1146C>T p.L382= | Silent (SNP) | VAF 17/68 reads (25%) | called by muse, mutect2, varscan2
- JCAD | c.1083G>A p.T361= | Silent (SNP) | VAF 10/203 reads (5%) | catalogued as rs943820942, COSV64757735; called by muse, mutect2
- KDM5D | c.1032G>A p.L344= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- KIF2B | c.1953T>A p.A651= | Silent (SNP) | VAF 16/134 reads (12%) | catalogued as rs369968440; called by muse, mutect2, varscan2
- LARP4 | c.1791A>G p.S597= | Silent (SNP) | VAF 28/170 reads (16%) | called by muse, varscan2
- LCE3D | c.144C>A p.S48= | Silent (SNP) | VAF 11/126 reads (9%) | called by muse, mutect2
- LHX5 | c.129C>T p.C43= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as rs201815436; called by muse, mutect2, varscan2
- MAGEC1 | c.729C>A p.S243= | Silent (SNP) | VAF 69/650 reads (11%) | called by muse, mutect2, varscan2
- MEGF8 | c.762G>T p.L254= | Silent (SNP) | VAF 12/95 reads (13%) | called by muse, mutect2, varscan2
- MKX | c.909G>A p.T303= | Silent (SNP) | VAF 20/274 reads (7%) | catalogued as rs769671412, COSV65393303; called by muse, mutect2
- MUC16 | c.24003G>T p.V8001= | Silent (SNP) | VAF 7/109 reads (6%) | called by muse, mutect2
- MXRA5 | c.3618G>C p.V1206= | Silent (SNP) | VAF 28/93 reads (30%) | catalogued as COSV54223934; called by muse, mutect2, varscan2
- MYH13 | c.5526G>A p.K1842= | Silent (SNP) | VAF 42/296 reads (14%) | catalogued as COSV99354328; called by muse, mutect2, varscan2
- NAA16 | c.1648A>C p.R550= | Silent (SNP) | VAF 25/135 reads (19%) | called by muse, mutect2, varscan2
- NIM1K | c.48T>C p.Y16= | Silent (SNP) | VAF 44/310 reads (14%) | called by muse, mutect2, varscan2
- NUMA1 | c.5808C>A p.T1936= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2, varscan2
- OASL | c.942A>T p.A314= | Silent (SNP) | VAF 21/127 reads (17%) | called by muse, mutect2, varscan2
- OR4P4 | c.885C>A p.A295= | Silent (SNP) | VAF 22/129 reads (17%) | called by muse, mutect2, varscan2
- OR5M1 | c.870T>C p.Y290= | Silent (SNP) | VAF 34/435 reads (8%) | called by muse, mutect2
- OR6M1 | c.855T>C p.F285= | Silent (SNP) | VAF 56/433 reads (13%) | called by muse, mutect2, varscan2
- OR6X1 | c.603C>A p.T201= | Silent (SNP) | VAF 18/276 reads (7%) | called by muse, mutect2
- OR8K1 | c.312C>A p.A104= | Silent (SNP) | VAF 24/415 reads (6%) | called by muse, mutect2
- OTOGL | c.408C>A p.G136= (on ENST00000547103; = p.G127= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 24/354 reads (7%) | called by muse, mutect2
- P3H2 | c.2001G>T p.L667= | Silent (SNP) | VAF 16/176 reads (9%) | called by muse, mutect2
- PADI1 | c.753G>T p.V251= | Silent (SNP) | VAF 20/346 reads (6%) | called by muse, mutect2
- PCDHA11 | c.1251G>A p.V417= | Silent (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2, varscan2
- PCDHA7 | c.1356C>A p.A452= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs185499663; called by muse, mutect2, varscan2
- PCDHGB2 | c.771G>T p.P257= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV53986951; called by muse, mutect2, varscan2
- PCSK5 | c.5082G>T p.V1694= | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- PIWIL4 | c.135C>T p.G45= | Silent (SNP) | VAF 7/156 reads (4%) | catalogued as rs1294794859; called by muse, mutect2
- PKHD1 | c.4620A>T p.T1540= | Silent (SNP) | VAF 12/129 reads (9%) | called by muse, mutect2
- PPARGC1A | c.174C>T p.C58= | Silent (SNP) | VAF 24/300 reads (8%) | called by muse, mutect2
- PRAMEF4 | c.531A>G p.K177= | Silent (SNP) | VAF 19/490 reads (4%) | called by muse, mutect2
- PRSS12 | c.570T>A p.V190= | Silent (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2, varscan2
- PTPRZ1 | c.1125C>A p.L375= | Silent (SNP) | VAF 12/58 reads (21%) | catalogued as COSV101100859; called by muse, mutect2
- RBPMS | c.99G>T p.L33= | Silent (SNP) | VAF 59/426 reads (14%) | called by muse, mutect2, varscan2
- RIMS2 | c.1534T>C p.L512= (on ENST00000666250 / NM_001348490.2; = p.L320= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 26/268 reads (10%) | called by muse, mutect2
- ROR2 | c.2517G>A p.P839= | Silent (SNP) | VAF 9/122 reads (7%) | catalogued as rs373575567, COSV65217824, COSV65224278; called by muse, mutect2
- SLC14A2 | c.2622G>C p.L874= | Silent (SNP) | VAF 16/360 reads (4%) | called by muse, mutect2
- SLCO4A1 | c.1242C>T p.F414= | Silent (SNP) | VAF 13/50 reads (26%) | catalogued as rs1163183483; called by muse, mutect2, varscan2
- SPINK7 | c.126C>A p.A42= | Silent (SNP) | VAF 68/368 reads (18%) | called by muse, mutect2, varscan2
- SRFBP1 | c.495C>T p.I165= | Silent (SNP) | VAF 18/169 reads (11%) | called by muse, mutect2, varscan2
- STAG3 | c.624T>C p.Y208= | Silent (SNP) | VAF 30/250 reads (12%) | called by muse, mutect2, varscan2
- TACC2 | c.6039C>T p.F2013= (on ENST00000334433; = p.F91= on NM_006997.4) | Silent (SNP) | VAF 15/66 reads (23%) | catalogued as COSV53279011; called by muse, mutect2, varscan2
- TMEM132A | c.1002A>T p.T334= | Silent (SNP) | VAF 6/38 reads (16%) | called by muse, mutect2
- TNN | c.135C>T p.T45= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs1298051893; called by muse, mutect2, varscan2
- TNRC6B | c.1509A>G p.T503= | Silent (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- TOX2 | c.1242G>T p.L414= (on ENST00000358131 / NM_001098798.2; = p.L390= on NM_032883.3) | Silent (SNP) | VAF 10/39 reads (26%) | called by muse, mutect2, varscan2
- TPR | c.3069A>G p.R1023= | Silent (SNP) | VAF 17/215 reads (8%) | called by muse, mutect2
- ULK4 | c.2691G>T p.L897= | Silent (SNP) | VAF 18/202 reads (9%) | called by muse, mutect2
- USH2A | c.4942C>T p.L1648= | Silent (SNP) | VAF 16/230 reads (7%) | catalogued as COSV56352095; called by muse, mutect2
- VAV3 | c.1599C>T p.L533= | Silent (SNP) | VAF 8/68 reads (12%) | catalogued as rs781650037; called by muse, mutect2, varscan2
- XDH | c.1722G>T p.V574= | Silent (SNP) | VAF 37/223 reads (17%) | called by muse, mutect2, varscan2
- XPO6 | c.3201A>G p.P1067= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs369570147; called by mutect2, varscan2
- YES1 | c.123A>G p.P41= | Silent (SNP) | VAF 37/402 reads (9%) | catalogued as rs530587098; called by muse, mutect2
- ZAN | c.7461C>A p.T2487= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2, varscan2
- ZNF165 | c.198A>T p.A66= | Silent (SNP) | VAF 10/90 reads (11%) | called by muse, mutect2, varscan2
- AL353804.4 | chrX:73820779 C>A | 3'Flank (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2
- BCR | c.1279+17086G>T | Intron (SNP) | VAF 28/280 reads (10%) | called by muse, mutect2
- FAM183BP | n.1327A>T | RNA (SNP) | VAF 30/420 reads (7%) | called by muse, mutect2
- IL36B | c.261+950T>A | Intron (SNP) | VAF 51/298 reads (17%) | called by muse, varscan2
- RNU7-174P | chr8:80559474 G>T | 5'Flank (SNP) | VAF 8/73 reads (11%) | called by muse, mutect2, varscan2
- TOR1AIP2 | c.-146-12073A>G | Intron (SNP) | VAF 29/282 reads (10%) | catalogued as COSV62625590; called by muse, mutect2, varscan2
- TP73-AS1 | n.1366G>A | RNA (SNP) | VAF 7/39 reads (18%) | catalogued as rs765615417; called by muse, mutect2, varscan2
- WNT3A | c.*741C>A | 3'UTR (SNP) | VAF 6/36 reads (17%) | called by muse, mutect2
